Surgical pathology report (de-identified scan), TCGA case TCGA-12-1597, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1597-01B (Primary Tumor).

Patient: [REDACTED]

TCGA-12-1597

AP Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain tumor- right frontal parietal.

GROSS EXAMINATION:

A. "Brain tumor (AF1)", received fresh for frozen section. An 11.0 x 9.0 x 3.0 cm mass of red-tan tissue with a distinct corticomedullary junction and a central area of soft amorphous pink-tan tissue is received. A representative section has been previously submitted as AF1, the frozen remnant is submitted in block A1. Representative sections of the remainder is submitted in blocks A2-A8.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

The tissue is brain that is infiltrated by a neoplastic proliferation of malignant glial cells associated with regions of necrosis pseudopalisaded by tumor cells, vascular proliferation, and mitotic activity.

DIAGNOSIS:

A. "BRAIN TUMOR":

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Electronically signed: [REDACTED]

Source: NCI Genomic Data Commons file cf917b34-7ac2-4f0d-94df-88c60e3000b9 (TCGA-12-1597.C29D6544-408E-4628-9B49-F3191F96BB0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).